Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A95W, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A95W-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-6-3
Melanoma NOS 8720/3
Site: Supraclavicular
Lymph node C77.0
QID 5/16/14

Specimen(s) Received:
LEFT SUPRACLAVICULAR BIOPSY

FINAL DIAGNOSIS

LYMPH NODE, SUPRACLAVICULAR LEFT, CORE BIOPSY

-METASTATIC MELANOMA

NOTE: Biopsy shows sheets of a cohesive intermediate sized celled malignant neoplasm. Tumor is strongly Melan-A and S100 positive, pan keratin and TTF-1 negative.

Pathologist:

*** Report Electronically Signed Out ***

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

Received in formalin, labeled with the patient's name and unit number only are multiple tan cylindrical soft tissues, aggregating 1.0 x 0.8 x 0.1 cm, which are submitted in toto in one cassette.

Summary of Stains Performed and Reviewed

	Count
Keratin, CK20 *	1
Keratin, CK7 *	1
Melan-A *	1
panCK *	1
S-100 Protein *	1
Thyroid Transcription Factor *	1

*The immunohistochemical profile may include the use of Analyte Specific Reagents, or Research Agents, whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the supplier. It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for this test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvements Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and Internal controls stained appropriately.

[page 2 of 2]
Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1] LEFT SUPRACLAVICULAR BIOPSY	1	[Undes]	(1)	[No Description]

Source: NCI Genomic Data Commons file e689b7b0-e09f-4492-b6ef-51a2163b945d (TCGA-DA-A95W.9BCAE0D2-7454-4CCD-9850-5260ED6A192C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).